RC case RC-B6SO — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5cdc2c3-1567-427b-b64a-4bd91e9d71fc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1965; Vital status: Alive; Country of birth: United States.

Diagnoses (4)
1. Anaplastic large cell lymphoma, T cell and Null cell type (the primary disease): ICD-O-3 morphology code: 9714/3; ICD-10 code: C84; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 47.5 years (17,348 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk; Sites of involvement: Bone, NOS / Breast, NOS.
   Pathology details: Greatest tumor dimension: 3.7 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 9 days; Days to treatment end: -176 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin; Initial disease status: Progressive Disease; Days to treatment start: 1,181 days (3.2 years); Days to treatment end: 1,274 days (3.5 years); Number of cycles: 4; Treatment outcome: Partial Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 1,381 days (3.8 years); Treatment outcome: Partial Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin; Initial disease status: Progressive Disease; Days to treatment start: 3,129 days (8.6 years); Days to treatment end: 3,500 days (9.6 years); Number of cycles: 12; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 50.7 years (18,515 days); Days to diagnosis: 1,167 days (3.2 years).
3. Progression (histology not recorded by GDC). Age at diagnosis: 51.0 years (18,643 days); Days to diagnosis: 1,295 days (3.5 years).
4. Recurrence (histology not recorded by GDC). Age at diagnosis: 56.0 years (20,456 days); Days to diagnosis: 3,108 days (8.5 years).

Follow-up (11 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 107 days; Disease response: Tumor Free.
- Day 1,167 (recurrence): Progression or recurrence: Yes; Days to recurrence: 1,167 days (3.2 years).
- Days to follow up: 1,232 days (3.4 years); Disease response: Partial Response.
- Day 1,295 (progression): Progression or recurrence: Yes; Days to progression: 1,295 days (3.5 years).
- Days to follow up: 1,498 days (4.1 years); Disease response: Partial Response.
- Days to follow up: 1,876 days (5.1 years); Disease response: Tumor Free.
- Day 3,108 (recurrence): Progression or recurrence: Yes; Days to recurrence: 3,108 days (8.5 years).
- Day 3,227 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Day 3,815 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day 3,111.

Molecular and laboratory tests
- Lactate Dehydrogenase 212 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 149 cm; BMI: 33.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SO-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SO-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SO-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 15.
